Somatic mutation profile of tumor specimen HCM-BROD-0793-C15-06A (aliquot HCM-BROD-0793-C15-06A-11D-A85K-36) from HCMI case HCM-BROD-0793-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,179 days).
Specimen HCM-BROD-0793-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e06bcb81-eafa-498d-8fc5-d2c4af6aa2e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0793-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0793-C15-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b53c497-b8c6-44ee-a297-b2c33482e427

The open-access MAF lists 158 somatic variants for this specimen: 101 protein-altering or splice-affecting, 48 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 48, Nonsense Mutation 7, Intron 4, 3'UTR 3, Frame Shift Del 3, Splice Region 2, In Frame Del 2, Nonstop Mutation 1, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 397/424 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCAT1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 209/3723 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753916893; called by muse, mutect2
- BRINP1 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 188/428 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs375138030; called by muse, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 55/239 reads (23%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- CABIN1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 203/588 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs567239001, COSV54077650; called by muse, mutect2, varscan2
- CCDC168 | c.10144dup p.R3382Kfs*19 | Frame Shift Ins (INS) | VAF 146/404 reads (36%) | catalogued as rs1183799771; called by mutect2, varscan2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 196/575 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2, varscan2
- CYYR1 | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 178/195 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54834792, COSV54835659; called by muse, mutect2, varscan2
- DCBLD2 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 128/304 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58788754; called by mutect2, varscan2
- DIDO1 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 252/525 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99825780; called by muse, mutect2, varscan2
- DNAH9 | c.11335C>T p.R3779* | Nonsense Mutation (SNP) | VAF 151/427 reads (35%) | catalogued as rs779176965, COSV52379299; called by muse, mutect2, varscan2
- EFCAB5 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 148/353 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1456302203; called by muse, mutect2, varscan2
- FSIP2 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 192/206 reads (93%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100554351; called by muse, mutect2, varscan2
- H3C2 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 224/518 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); catalogued as COSV52520062; called by muse, mutect2, varscan2
- HK1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 135/354 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs747711080, COSV53859600; called by muse, mutect2, varscan2
- IL31RA | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs921624282, COSV51683882; called by muse, mutect2
- IPO8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 192/376 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs778254539, COSV56240309; called by muse, mutect2, varscan2
- JPH1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 314/595 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs769389782; called by muse, mutect2, varscan2
- KLF15 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 26/649 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1281213893, COSV99955167; called by muse, mutect2
- KRT33B | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 175/408 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs370317934; called by muse, mutect2, varscan2
- KRTAP26-1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 202/228 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV62129072; called by muse, varscan2
- LRFN1 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 512/844 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1311724284, COSV50435653; called by muse, mutect2, varscan2
- LRRFIP2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 187/510 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs765165432, COSV104414724; called by muse, mutect2, varscan2
- LVRN | c.1390del p.S464Lfs*15 | Frame Shift Del (DEL) | VAF 88/254 reads (35%) | catalogued as rs756702147; called by pindel, varscan2
- MMP8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs563802778; called by muse, mutect2, varscan2
- MUC4 | c.4468C>T p.P1490S | Missense Mutation (SNP) | VAF 212/339 reads (63%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.65); catalogued as rs1233126201; called by muse, mutect2, varscan2
- NFKBID | c.580C>T p.Q194* (on ENST00000396901; = p.Q346* on NM_032721.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/632 reads (3%) | catalogued as COSV61728329; called by muse, mutect2
- OR51D1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 538/571 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031260747; called by muse, mutect2, varscan2
- PCDHGC5 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 44/1184 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs749918160, COSV52753161; called by muse, mutect2
- POTEC | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 310/759 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as rs879248532; called by muse, mutect2, varscan2
- PPP1R3A | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV52889490; called by muse, mutect2, varscan2
- PTPN18 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 194/485 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.161); catalogued as rs765171238; called by muse, mutect2, varscan2
- RELL2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 210/1107 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs146456008; called by muse, mutect2, varscan2
- RSPO3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 14/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259278709, COSV63152885; called by muse, mutect2
- RTL1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 206/513 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1361005947, COSV66017334; called by muse, mutect2, varscan2
- RTL5 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 177/189 reads (94%) | catalogued as rs767497557; called by muse, mutect2, varscan2
- SHANK1 | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 327/482 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); catalogued as COSV99521896; called by muse, mutect2, varscan2
- SSRP1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 194/617 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53480438; called by muse, mutect2, varscan2
- STAG1 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs753635471; called by muse, mutect2, varscan2
- STS | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs144731434; called by muse, mutect2
- TFR2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 599/708 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs751548369; called by muse, mutect2, varscan2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 232/471 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- UBE3B | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs372352298; called by muse, mutect2, varscan2
- ZNF175 | c.1208A>C p.N403T | Missense Mutation (SNP) | VAF 193/272 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs756933793; called by muse, mutect2, varscan2
- ZNF28 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 225/312 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781145103; called by muse, mutect2, varscan2
- ZNF43 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 193/380 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.261); catalogued as COSV61684309; called by muse, mutect2, varscan2
- ACOX1 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 12/397 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2
- ACSM3 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 89/425 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC50 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 128/385 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH2 | c.1078T>A p.Y360N | Missense Mutation (SNP) | VAF 25/870 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP152 | c.3548A>C p.Q1183P | Missense Mutation (SNP) | VAF 25/466 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- CTNND2 | c.1123C>A p.H375N | Missense Mutation (SNP) | VAF 588/659 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DCHS2 | n.235T>G | Splice Region (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- DCP1B | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 243/739 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKQ | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 248/478 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH6 | c.11303T>C p.L3768S | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHX4 | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ERBB4 | c.2209T>C p.W737R | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOSC4 | c.738A>T p.*246Cext*9 | Nonstop Mutation (SNP) | VAF 282/447 reads (63%) | called by muse, mutect2, varscan2
- FAM47C | c.497_501del p.E166Afs*6 | Frame Shift Del (DEL) | VAF 142/226 reads (63%) | called by mutect2, pindel, varscan2
- FBXL19 | c.1528C>T p.L510= | Splice Region (SNP) | VAF 32/644 reads (5%) | called by muse, mutect2
- FOXG1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 346/764 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FZD6 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 144/512 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GABBR1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 231/553 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- GBF1 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GLIS3 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GOLGA2 | c.712del p.E238Sfs*40 | Frame Shift Del (DEL) | VAF 157/572 reads (27%) | called by mutect2, pindel, varscan2
- GTF3C3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 189/532 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.257); called by muse, varscan2
- HHLA1 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 128/540 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- HOMER2 | c.967A>G p.K323E (on ENST00000304231 / NM_199330.3; = p.K312E on NM_004839.4) | Missense Mutation (SNP) | VAF 293/543 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HOXD11 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.399); called by muse, varscan2
- HPSE2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 193/442 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- IRF2BP1 | c.679A>C p.K227Q | Missense Mutation (SNP) | VAF 330/940 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ITGB1BP2 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); called by muse, mutect2
- LRRC14B | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 40/1011 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2
- MAPK9 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 19/685 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2
- MARF1 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 19/648 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.236); called by muse, mutect2
- NOMO1 | c.3475G>C p.G1159R | Missense Mutation (SNP) | VAF 132/1272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOVA1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 23/569 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- OLFM3 | c.224A>C p.N75T (on ENST00000338858 / NM_001288821.1; = p.N55T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/400 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR2M4 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ORC5 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- PITHD1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- POT1 | c.968_970del p.L323del | In Frame Del (DEL) | VAF 81/102 reads (79%) | called by mutect2, pindel, varscan2
- POTEC | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PPP2R3A | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RORA | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 172/468 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, varscan2
- RPP40 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 123/283 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SELP | c.1856C>A p.S619Y | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by mutect2, varscan2
- SHISA7 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- SIN3B | c.3126G>A p.W1042* | Nonsense Mutation (SNP) | VAF 301/704 reads (43%) | called by muse, mutect2, varscan2
- SLC6A1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- TENM2 | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 346/478 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- UAP1L1 | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 27/1080 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- VPS13B | c.9559G>A p.G3187S | Missense Mutation (SNP) | VAF 181/655 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WBP2NL | c.709_712delinsA p.G237_Y238delinsN | In Frame Del (DEL) | VAF 203/335 reads (61%) | called by pindel, varscan2*
- ZFP36L2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 280/677 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFP82 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 248/752 reads (33%) | called by muse, mutect2, varscan2
- ZNF329 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 24/644 reads (4%) | called by muse, mutect2
- ZNF510 | c.1490T>C p.F497S | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF550 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 262/554 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGO1 | c.2517C>T p.A839= | Silent (SNP) | VAF 180/716 reads (25%) | called by muse, mutect2, varscan2
- APP | c.2229C>A p.T743= | Silent (SNP) | VAF 18/243 reads (7%) | called by muse, mutect2
- CEP128 | c.1779C>T p.S593= | Silent (SNP) | VAF 192/418 reads (46%) | catalogued as rs139506469; called by muse, mutect2, varscan2
- CHGB | c.93A>T p.G31= | Silent (SNP) | VAF 131/311 reads (42%) | called by muse, mutect2, varscan2
- CLC | c.351G>A p.K117= | Silent (SNP) | VAF 215/419 reads (51%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.939A>T p.P313= | Silent (SNP) | VAF 124/223 reads (56%) | catalogued as rs1255174102; called by muse, mutect2, varscan2
- DSP | c.4989C>T p.A1663= | Silent (SNP) | VAF 194/448 reads (43%) | called by muse, mutect2, varscan2
- ELFN1 | c.150C>T p.P50= | Silent (SNP) | VAF 889/1315 reads (68%) | catalogued as rs757471650; called by muse, mutect2, varscan2
- EXOC6 | c.2140C>T p.L714= | Silent (SNP) | VAF 26/383 reads (7%) | called by muse, mutect2
- F13A1 | c.1695G>T p.P565= | Silent (SNP) | VAF 302/630 reads (48%) | called by muse, mutect2
- FBXO42 | c.870C>G p.V290= | Silent (SNP) | VAF 134/707 reads (19%) | catalogued as rs552728510; called by muse, mutect2, varscan2
- FCGR2A | c.207G>A p.E69= (on ENST00000271450 / NM_001136219.3; = p.E68= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 504/538 reads (94%) | catalogued as rs1487882177; called by muse, mutect2
- FREM1 | c.6286A>C p.R2096= | Silent (SNP) | VAF 32/373 reads (9%) | called by muse, mutect2
- GOLGA6L2 | c.1941G>A p.A647= | Silent (SNP) | VAF 328/792 reads (41%) | catalogued as rs1460236557; called by mutect2, varscan2
- HDAC4 | c.930C>T p.V310= | Silent (SNP) | VAF 28/955 reads (3%) | called by muse, mutect2
- HSPA1L | c.279T>C p.P93= | Silent (SNP) | VAF 42/796 reads (5%) | called by muse, mutect2
- IRF2 | c.594C>T p.D198= | Silent (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- KCTD8 | c.249C>T p.A83= | Silent (SNP) | VAF 200/336 reads (60%) | called by muse, varscan2
- KIF26A | c.315C>T p.L105= | Silent (SNP) | VAF 29/680 reads (4%) | catalogued as rs780500407; called by muse, mutect2
- KLHL41 | c.1194T>C p.D398= | Silent (SNP) | VAF 15/493 reads (3%) | catalogued as COSV52930064; called by muse, mutect2
- L3MBTL3 | c.132A>G p.E44= | Silent (SNP) | VAF 122/325 reads (38%) | called by muse, mutect2, varscan2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as rs369104625; called by muse, mutect2
- MAGEL2 | c.1878C>T p.I626= | Silent (SNP) | VAF 224/614 reads (36%) | called by muse, mutect2, varscan2
- MASP2 | c.1143A>T p.T381= | Silent (SNP) | VAF 297/630 reads (47%) | called by muse, mutect2, varscan2
- MAT1A | c.1182A>C p.V394= | Silent (SNP) | VAF 146/342 reads (43%) | called by muse, mutect2, varscan2
- MECOM | c.1809T>A p.P603= (on ENST00000468789 / NM_001105078.4; = p.P791= on NM_004991.4) | Silent (SNP) | VAF 32/616 reads (5%) | called by muse, mutect2
- MICAL2 | c.687G>T p.L229= | Silent (SNP) | VAF 113/413 reads (27%) | called by muse, mutect2, varscan2
- MICAL2 | c.1179G>A p.V393= | Silent (SNP) | VAF 304/322 reads (94%) | called by muse, varscan2
- MLXIPL | c.468G>A p.A156= | Silent (SNP) | VAF 267/814 reads (33%) | catalogued as rs1554598716; called by muse, mutect2, varscan2
- MYCT1 | c.660G>A p.P220= | Silent (SNP) | VAF 214/502 reads (43%) | catalogued as rs773532214; called by muse, varscan2
- NOTCH1 | c.3261C>T p.S1087= | Silent (SNP) | VAF 555/897 reads (62%) | catalogued as rs543586029; called by muse, mutect2, varscan2
- NUTM2G | c.1590C>T p.V530= | Silent (SNP) | VAF 71/1297 reads (5%) | called by muse, mutect2
- OR10A2 | c.453C>T p.F151= | Silent (SNP) | VAF 187/593 reads (32%) | catalogued as rs1473595599, COSV56299079; called by muse, mutect2, varscan2
- PABPC1L | c.45G>A p.V15= | Silent (SNP) | VAF 250/508 reads (49%) | catalogued as rs1371060902; called by muse, mutect2, varscan2
- PARG | c.2871C>T p.Y957= | Silent (SNP) | VAF 110/367 reads (30%) | called by muse, mutect2, varscan2
- PCDHA11 | c.2160G>C p.L720= | Silent (SNP) | VAF 250/1122 reads (22%) | called by muse, mutect2, varscan2
- SEMA6A | c.1206G>T p.V402= | Silent (SNP) | VAF 164/363 reads (45%) | called by muse, mutect2, varscan2
- SHROOM2 | c.2457C>T p.H819= | Silent (SNP) | VAF 316/367 reads (86%) | catalogued as rs1430388211, COSV66607978; called by muse, mutect2, varscan2
- SLC4A1AP | c.1104G>A p.K368= | Silent (SNP) | VAF 135/410 reads (33%) | called by muse, mutect2, varscan2
- SNRK | c.759T>C p.D253= | Silent (SNP) | VAF 124/246 reads (50%) | called by muse, mutect2, varscan2
- SPDYE6 | c.807C>T p.I269= | Silent (SNP) | VAF 421/1692 reads (25%) | called by muse, mutect2, varscan2
- TLN2 | c.3303C>A p.G1101= | Silent (SNP) | VAF 24/456 reads (5%) | called by muse, mutect2
- TMCC2 | c.786C>T p.A262= | Silent (SNP) | VAF 223/831 reads (27%) | catalogued as rs769302375; called by muse, mutect2, varscan2
- TPO | c.165C>T p.Y55= | Silent (SNP) | VAF 221/512 reads (43%) | catalogued as rs149346954, CM1510459, COSV61101360; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRBV2 | c.15C>T p.L5= | Silent (SNP) | VAF 120/387 reads (31%) | catalogued as rs776577517; called by muse, mutect2, varscan2
- WNT5B | c.579C>G p.G193= | Silent (SNP) | VAF 23/589 reads (4%) | called by muse, mutect2
- ZNF234 | c.1116C>T p.Y372= | Silent (SNP) | VAF 244/730 reads (33%) | catalogued as rs766123560, COSV70602772; called by muse, mutect2, varscan2
- ZNF439 | c.1143G>A p.P381= | Silent (SNP) | VAF 183/444 reads (41%) | catalogued as rs201064778, COSV58309103; called by muse, mutect2, varscan2
- AGAP1 | c.164-38205_164-38198del | Intron (DEL) | VAF 218/552 reads (39%) | called by mutect2, pindel, varscan2
- COL6A5 | c.*344G>A | 3'UTR (SNP) | VAF 158/340 reads (46%) | catalogued as COSV55205626; called by muse, mutect2, varscan2
- ENPP2 | c.973-2114C>T | Intron (SNP) | VAF 167/529 reads (32%) | catalogued as rs540074619, COSV50014744; called by muse, mutect2, varscan2
- MIEF1 | c.*948G>A | 3'UTR (SNP) | VAF 17/324 reads (5%) | called by muse, mutect2
- NRXN3 | c.-1C>A | 5'UTR (SNP) | VAF 15/324 reads (5%) | called by muse, mutect2
- SPEF2 | c.4448-3087G>T | Intron (SNP) | VAF 964/1017 reads (95%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*130G>A | 3'UTR (SNP) | VAF 251/591 reads (42%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1245T>C | Intron (SNP) | VAF 154/346 reads (45%) | called by muse, mutect2, varscan2
- ZNF772 | chr19:57467042 T>C | 3'Flank (SNP) | VAF 173/505 reads (34%) | called by muse, mutect2, varscan2
